Somatic mutation profile of tumor specimen BA3255D (aliquot aq-BA3255D) from BEATAML1.0 case 2725, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.8 years (20,384 days).
Specimen BA3255D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8821f06-e031-4a47-a2cc-347d7022f309.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3346D (Solid Tissue Normal), aliquot aq-BA3346D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7562ce30-0865-435a-b563-6a21dd8eeb6d

The open-access MAF lists 9 somatic variants for this specimen: 9 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Frame Shift Ins 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND3 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 13/118 reads (11%) | hotspot (GDC flag); catalogued as COSV57828583; called by muse, mutect2, varscan2
- ABL1 | c.2075C>T p.T692M | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs1332380683; called by muse, mutect2, varscan2
- NIN | c.3359C>T p.A1120V | Missense Mutation (SNP) | VAF 163/307 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs375931384; called by muse, mutect2, varscan2
- VASN | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.096); catalogued as rs1403763410; called by muse, mutect2, varscan2
- EXPH5 | c.2511_2514del p.N837Kfs*16 | Frame Shift Del (DEL) | VAF 132/303 reads (44%) | called by mutect2, pindel, varscan2
- GOLGA6L10 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.097); called by muse, varscan2
- KMT2A | c.375C>A p.N125K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.858dup p.K287* | Frame Shift Ins (INS) | VAF 23/206 reads (11%) | called by mutect2, pindel, varscan2
- REV3L | c.3031dup p.M1011Nfs*5 | Frame Shift Ins (INS) | VAF 123/299 reads (41%) | called by mutect2, pindel, varscan2
